Somatic mutation profile of tumor specimen TCGA-NQ-A57I-01A (aliquot TCGA-NQ-A57I-01A-11D-A34C-32) from TCGA case TCGA-NQ-A57I, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mesothelioma, biphasic, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IB; Age at diagnosis: 71.8 years (26,212 days).
Specimen TCGA-NQ-A57I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3e2bff5-f082-4fe1-9aab-317d47497707.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NQ-A57I-10A (Blood Derived Normal), aliquot TCGA-NQ-A57I-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8162a04-3878-4a02-a7d3-1a7969b8b09e

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Frame Shift Del 3, Nonsense Mutation 1, Intron 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 55/79 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- MYPN | c.3214C>T p.R1072* | Nonsense Mutation (SNP) | VAF 22/37 reads (59%) | catalogued as rs1057519573, COSV62741958; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.701A>G p.Y234C | Missense Mutation (SNP) | VAF 17/31 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs587780073, CM035576, COSV52661201, COSV52686167, COSV53142556; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARFGEF2 | c.2018C>T p.T673M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs761318717; called by muse, varscan2
- FAM135B | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370398438; called by muse, mutect2, varscan2
- JADE1 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1377908620, COSV56904356; called by muse, mutect2, varscan2
- KALRN | c.5923G>A p.V1975M (on ENST00000360013 / NM_001024660.4; = p.V278M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1287328692; called by muse, mutect2
- KIF26A | c.5294C>T p.T1765I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs1033608572; called by muse, mutect2, varscan2
- LMO4 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV100983992; called by muse, mutect2, varscan2
- MUC16 | c.17290A>C p.T5764P | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV67464323; called by muse, mutect2, varscan2
- OR8G1 | c.55del p.E19Nfs*14 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | catalogued as COSV58383249; called by mutect2, pindel, varscan2
- PRICKLE1 | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV100566164; called by muse, mutect2, varscan2
- ANKS6 | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ARID2 | c.3738_3739del p.E1247Gfs*13 | Frame Shift Del (DEL) | VAF 68/160 reads (43%) | called by mutect2, pindel, varscan2
- DNHD1 | c.1082T>G p.I361S | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EPHA1 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- F11R | c.196C>A p.Q66K | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- H1-2 | c.513del p.K172Rfs*22 | Frame Shift Del (DEL) | VAF 23/128 reads (18%) | called by mutect2, pindel, varscan2
- KRT36 | c.291_294delinsT p.M97_Q98delinsI | In Frame Del (DEL) | VAF 20/33 reads (61%) | called by pindel, varscan2*
- LZTS1 | c.550A>C p.T184P | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- MAPKBP1 | c.3955G>A p.G1319S (on ENST00000456763 / NM_001128608.2; = p.G1313S on NM_014994.3) | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MUC16 | c.18779C>A p.A6260E | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PM20D2 | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, varscan2
- SGSH | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.917); called by muse, mutect2
- SLC5A9 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UTP20 | c.2351T>C p.V784A | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF582 | c.419A>T p.H140L | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BICRA | c.3633C>T p.P1211= | Silent (SNP) | VAF 32/133 reads (24%) | called by muse, mutect2, varscan2
- C1orf94 | c.969G>A p.K323= (on ENST00000488417 / NM_001134734.2; = p.K133= on NM_032884.5) | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- CHD2 | c.3672A>G p.Q1224= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs768542034; called by muse, mutect2, varscan2
- GCOM1 | c.234A>G p.R78= | Silent (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- INTS1 | c.4290C>T p.F1430= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- KMT2A | c.237C>G p.A79= | Silent (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- RCC2 | c.918A>G p.E306= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs554058168; called by mutect2, varscan2
- SIGLEC10 | c.618C>T p.P206= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- ZFP90 | c.786C>G p.T262= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- ZFR2 | c.1935C>T p.S645= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs912474787; called by muse, mutect2, varscan2
- C15orf65 | c.19-90C>A | Intron (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2
- SPACA6 | chr19:51692675 C>T | 5'Flank (SNP) | VAF 18/89 reads (20%) | called by muse, varscan2
